Gene-level copy-number profile of tumor specimen TCGA-22-5483-01A from TCGA case TCGA-22-5483, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.2 years (27,109 days).
Specimen TCGA-22-5483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.5c12ce70-777f-4a04-b7b4-24fa4a9609bf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5483-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c174e591-dde4-4dbe-a232-e58cff1631bd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 1,165; copy number 2: 19,267; copy number 3: 18,766; copy number 4: 16,377; copy number 5: 3,623; copy number 6: 417; copy number 7: 42; copy number 8: 93; copy number 9: 42; copy number 14: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5483-01A-01D-1816-01): tumor purity 0.7, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:87,792,492–90,261,708, 21 genes (within-gene range 0–1): HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,221 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,154,761–37,325,100, 1 gene, copy number 14 (within-gene range 2–14): AL353604.1.
- chr1:37,203,610–43,389,808, 207 genes, copy number 6–14 (broad region; genes not listed).
- chr3:93,843,764–106,427,977, 147 genes, copy number 6 (broad region; genes not listed).
- chr3:106,515,897–106,691,320, 3 genes, copy number 6: Y_RNA, AC080097.1, Y_RNA.
- chr5:1,931,064–52,080,987, 661 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:41,934,934–42,868,560, 19 genes, copy number 5 (within-gene range 4–5): CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1, AL591473.1, UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC, BICRAL.
- chr6:91,390,313–94,447,179, 29 genes, copy number 5: AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7, AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr7:57,772,584–159,233,377, 1,947 genes, copy number 5 (broad region; genes not listed).
- chr9:85,369,591–105,851,425, 414 genes, copy number 5–8 (broad region; genes not listed).
- chr9:106,061,354–106,064,825, 1 gene, copy number 7: AL732323.1.
- chr13:23,979,700–30,684,278, 150 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr18:64,041,555–66,069,647, 14 genes, copy number 5 (within-gene range 4–5): LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1.
- chr20:87,250–32,439,319, 628 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 173. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
